Somatic mutation profile of tumor specimen TARGET-20-PATJWN-09A (aliquot TARGET-20-PATJWN-09A-01D) from TARGET case TARGET-20-PATJWN, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,539 days).
Specimen TARGET-20-PATJWN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f92f389-bd90-49de-9cf9-c23555314d0d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATJWN-14A (Bone Marrow Normal), aliquot TARGET-20-PATJWN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e525c658-1251-44bb-9661-522a9fc47076

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2028C>A p.N676K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519766, COSV54042688, COSV54051954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GATA2 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141458, COSV62002954; called by muse, mutect2, varscan2
- RUNX1T1 | c.1006C>T p.R336C (on ENST00000265814 / NM_001198628.1; = p.R309C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as rs1158790160, COSV56150330, COSV56152929; called by muse, mutect2, varscan2
- LRP6 | c.*2099A>G | 3'UTR (SNP) | VAF 30/148 reads (20%) | called by muse, mutect2, varscan2
